Somatic mutation profile of tumor specimen ddc680ad-63cf-4807-b535-9ccc88 (aliquot ddc680ad-63cf-4807-b535-9ccc88_D6_1) from CPTAC case 11BR014, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 39.3 years (14,356 days).
Specimen ddc680ad-63cf-4807-b535-9ccc88: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 60f23eee-1c22-4a3c-81d5-4052b2cfdd7a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 5da4ac87-0990-419c-88c1-acd047 (Blood Derived Normal), aliquot 5da4ac87-0990-419c-88c1-acd047_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/efbf6988-7972-48bd-a4a1-c2334210990b

The open-access MAF lists 34 somatic variants for this specimen: 30 protein-altering or splice-affecting, 1 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Frame Shift Del 2, Intron 2, Splice Site 1, In Frame Del 1, Frame Shift Ins 1, 3'UTR 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 14/53 reads (26%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PIK3CA | c.2176G>A p.E726K | Missense Mutation (SNP) | VAF 27/112 reads (24%) | hotspot (GDC flag); SIFT tolerated (0.36); PolyPhen benign (0.396); catalogued as rs867262025, CM126693, COSV55875460; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAMTS3 | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 46/210 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as rs1017254734, COSV54384432; called by muse, mutect2, varscan2
- GLP2R | c.655G>T p.A219S | Missense Mutation (SNP) | VAF 63/211 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as COSV52322388; called by muse, mutect2, varscan2
- LTBP1 | c.4834+1G>A p.X1612_splice (on ENST00000404816 / NM_206943.4; = p.X1286_splice on NM_000627.4) | Splice Site (SNP) | VAF 28/101 reads (28%) | catalogued as rs758786612; called by muse, mutect2, varscan2
- MAP3K1 | c.4250C>T p.A1417V | Missense Mutation (SNP) | VAF 54/382 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1358646708, COSV68127001; called by muse, mutect2, varscan2
- NALCN | c.4718G>A p.R1573H | Missense Mutation (SNP) | VAF 33/136 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs767166593, COSV51950570; called by muse, mutect2, varscan2
- PJA1 | c.206G>A p.R69Q | Missense Mutation (SNP) | VAF 63/235 reads (27%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.978); catalogued as rs781679698; called by muse, mutect2, varscan2
- SNX30 | c.1117G>A p.E373K | Missense Mutation (SNP) | VAF 18/154 reads (12%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.967); catalogued as rs1159380755, COSV65292374; called by muse, mutect2, varscan2
- TP53BP2 | c.1765C>T p.R589W (on ENST00000343537 / NM_001031685.3; = p.R460W on NM_005426.2) | Missense Mutation (SNP) | VAF 82/405 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs767882716, COSV59069268; called by muse, mutect2, varscan2
- ABHD15 | c.121G>T p.A41S | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADRA2C | c.1188C>A p.F396L | Missense Mutation (SNP) | VAF 39/176 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- APBA1 | c.106G>C p.E36Q | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- CASKIN1 | c.1154G>A p.G385E | Missense Mutation (SNP) | VAF 29/225 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- CBFB | c.57del p.K20Sfs*2 | Frame Shift Del (DEL) | VAF 4/30 reads (13%) | called by mutect2, pindel, varscan2
- COMMD1 | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 68/310 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.698); called by muse, mutect2, varscan2
- DLGAP1 | c.1210A>C p.S404R | Missense Mutation (SNP) | VAF 47/170 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAJB13 | c.710C>T p.P237L | Missense Mutation (SNP) | VAF 28/138 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- GPSM1 | c.1031G>A p.R344H | Missense Mutation (SNP) | VAF 17/208 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.171); called by muse, mutect2
- IP6K1 | c.923T>G p.F308C | Missense Mutation (SNP) | VAF 69/333 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- KMT2C | c.10729dup p.T3577Nfs*19 | Frame Shift Ins (INS) | VAF 57/308 reads (19%) | called by mutect2, pindel, varscan2
- MAN2A1 | c.1876G>C p.D626H | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- MAP3K1 | c.1168del p.Q390Rfs*46 | Frame Shift Del (DEL) | VAF 28/173 reads (16%) | called by mutect2, pindel, varscan2
- MUC5B | c.6806G>A p.G2269E | Missense Mutation (SNP) | VAF 77/409 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- PHIP | c.5162_5164del p.K1721del | In Frame Del (DEL) | VAF 37/251 reads (15%) | called by mutect2, pindel, varscan2
- POLR1G | c.1186A>C p.T396P | Missense Mutation (SNP) | VAF 33/164 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- PYGO1 | c.860G>A p.S287N | Missense Mutation (SNP) | VAF 36/171 reads (21%) | SIFT tolerated (0.89); PolyPhen benign (0); called by muse, mutect2, varscan2
- RGSL1 | c.3170C>G p.S1057C | Missense Mutation (SNP) | VAF 86/364 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- SNX15 | c.391C>T p.P131S | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.307); called by muse, mutect2, varscan2
- STX11 | c.367G>T p.A123S | Missense Mutation (SNP) | VAF 82/376 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- AMOT | c.1500G>A p.E500= (on ENST00000371959 / NM_001113490.1; = p.E91= on NM_133265.3) | Silent (SNP) | VAF 14/157 reads (9%) | called by muse, mutect2
- EI24 | c.189-382C>T | Intron (SNP) | VAF 9/50 reads (18%) | called by muse, mutect2, varscan2
- MIGA2 | c.1270-106G>A | Intron (SNP) | VAF 18/107 reads (17%) | catalogued as rs759236840, COSV99477930; called by muse, mutect2, varscan2
- SUFU | c.*21G>A | 3'UTR (SNP) | VAF 58/234 reads (25%) | catalogued as rs1459618360; called by muse, mutect2, varscan2
